CPTAC case C3N-03612 — Oropharynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Oropharynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6d6c315-2b2e-4347-9c38-8784d15192fb

Demographics
Sex at birth: male; Race: white; Year of birth: 1966; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Oropharynx, NOS; Site of resection or biopsy: Oropharynx, NOS; Age at diagnosis: 51.6 years (18,832 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 697 days (1.9 years); Progression or recurrence: no; Days to last follow up: 697 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 331 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 697 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 697 days (1.9 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 91 kg; Height: 174 cm; BMI: 30.06.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03612-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 28 days; Initial weight: 350 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide C3N-03612-23: Section location: Oropharynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03612-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 28 days; Initial weight: 200 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03612-13: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 28 days; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03612-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 28 days; Method of sample procurement: Blood Draw.
